Gene-level copy-number profile of tumor specimen TCGA-ZM-AA0B-01A from TCGA case TCGA-ZM-AA0B, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 32.4 years (11,820 days).
Specimen TCGA-ZM-AA0B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.a3c7fcb5-5b5f-424e-92d8-a756b5e16cd3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZM-AA0B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a2ddc79c-8a98-4c8b-92b6-d098fa7a1200

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,559; copy number 2: 13,003; copy number 3: 29,373; copy number 4: 13,931; copy number 5: 818; copy number 6: 601; copy number 9: 179; copy number 15: 97; copy number 19: 8; copy number 24: 11; copy number 30: 111; copy number 33: 126.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZM-AA0B-01A-11D-A434-01): tumor purity 0.48, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 532 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:22,409,237–34,249,958, 231 genes, copy number 15–33 (within-gene range 6–33) (broad region; genes not listed).
- chr12:57,546,026–73,846,188, 301 genes, copy number 9–30 (within-gene range 3–30) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,559. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
